Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0I5, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0I5-01A (Primary Tumor).

1CD-0-3

Carcinoma, ductal, NOS 8500/3

1/17/11
fw

Site Code: breast, NOS 8500.9

Collection Date:

Sex: F

Date of Birth:

ars

Order Doctor:

Not for patient's chart

*DIAGNOSIS

ORIGINAL TEXT:

FEMALE BREAST, RIGHT

RIGHT BREAST MASS; MULTIFOCAL INTRADUCTAL AND INFILTRATING

DUCTAL CARCINOMA, GRADE 2/3, NUCLEAR GRADE MODERATELY

DIFFERENTIATED, THE TUMOR EXTENDS TO WITHIN 0.1MM OF THE
SURGICAL MARGIN.

ORIGINAL VER ID

AT 00:00 BY

*** End of Report ***

Source: NCI Genomic Data Commons file 56dcda9c-6c8b-4e4a-8ca9-9188fac4a611 (TCGA-B6-A0I5.FA43414D-3757-43CC-8949-77F82DF4FA4D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).